MMRF case MMRF_2266 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/5ac88dea-a26f-4af1-afb9-9bcfe937db6b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Dead; Days to death: 519 days (1.4 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.7 years (26,909 days); ISS stage: II; Days to last known disease status: 519 days (1.4 years); Days to last follow up: 519 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 68 days; Days to treatment end: 369 days (1.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 519.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 3): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1830 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.642 mg/dL; Immunoglobulin G 2.97 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 3.5 µg/mL; Hemoglobin 5.52 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.53 mmol/L; Albumin 34 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 89 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Hemoglobin 7.63 mmol/L; Leukocytes 11 ×10⁹/L; Absolute Neutrophil 9.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 8.09 mmol/L.
- Day 155 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.911 mg/dL; Hemoglobin 8.8 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.5 mmol/L.
- Day 257 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Hemoglobin 8.99 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 6.1 g/dL; Glucose 5.94 mmol/L.
- Day 348 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 2.65 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.766 mg/dL; Hemoglobin 9.05 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 109 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 38 g/L; Total Protein 6.5 g/dL; Glucose 7.98 mmol/L.
- Day 412 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 2.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.38 mg/dL; Immunoglobulin G 5.73 g/L; Immunoglobulin A 0.657 g/L; Immunoglobulin M 0.699 g/L; Hemoglobin 9.61 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6.5 ×10⁹/L; Platelets 187 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 3.63 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 177 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2266_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2266_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
